Somatic mutation profile of tumor specimen TCGA-KT-A7W1-01A (aliquot TCGA-KT-A7W1-01A-11D-A34A-08) from TCGA case TCGA-KT-A7W1, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 45.3 years (16,560 days).
Specimen TCGA-KT-A7W1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecfbf158-4396-4d0a-bfcd-6d91fdd99f0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KT-A7W1-10A (Blood Derived Normal), aliquot TCGA-KT-A7W1-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6ed50a8-95a8-4d1e-9f8e-673bba16fbd2

The open-access MAF lists 44 somatic variants for this specimen: 28 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 14, Nonsense Mutation 4, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 54/142 reads (38%) | catalogued as rs128626235, CD951679, CM940337, COSV99920124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 554/2734 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs727504256, COSV51767260, COSV51795875; ClinVar: drug response; called by muse, varscan2
- PIK3CA | c.2702G>T p.C901F | Missense Mutation (SNP) | VAF 87/208 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55881149; called by muse, mutect2, varscan2
- ADCY2 | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV100602026; called by muse, mutect2, varscan2
- ARHGEF6 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs144171880, COSV51690767; called by muse, mutect2, varscan2
- BAIAP3 | c.2486G>A p.G829E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV99136141; called by muse, mutect2, varscan2
- C1QTNF9B | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101158531; called by muse, mutect2, varscan2
- ELF1 | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs750270245, COSV99522875; called by muse, mutect2, varscan2
- ELOA2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.041); catalogued as rs149522210; called by muse, mutect2, varscan2
- ERCC2 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs778075234, COSV101228708; called by muse, mutect2, varscan2
- FST | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.369); catalogued as rs747039800, COSV99887051; called by muse, mutect2, varscan2
- GPR139 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs556069972, COSV58503875; called by muse, mutect2, varscan2
- GRIN2A | c.4223C>T p.T1408M | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs763219483, COSV58061178; called by muse, mutect2, varscan2
- HCFC1 | c.4925C>T p.A1642V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as rs782330667, COSV100128570; called by muse, mutect2, varscan2
- L3MBTL2 | c.1348G>A p.V450I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV99345712; called by muse, mutect2, varscan2
- MAST3 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766369438, COSV53218215; called by muse, varscan2
- MDM2 | c.620T>A p.V207E | Missense Mutation (SNP) | VAF 56/119 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99254391; called by muse, mutect2, varscan2
- OR4S1 | c.404A>G p.D135G | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100180191; called by muse, mutect2, varscan2
- OR51E2 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV101211324; called by muse, mutect2, varscan2
- PDZD4 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99381110; called by muse, mutect2, varscan2
- RNF167 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | catalogued as COSV99337263; called by muse, mutect2
- SLC9A7 | c.2107C>A p.L703M | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV60381973; called by muse, mutect2, varscan2
- TKTL2 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 38/106 reads (36%) | catalogued as COSV54918978, COSV99761172; called by muse, mutect2, varscan2
- TMEM132D | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as rs756275076, COSV70594065; called by muse, mutect2, varscan2
- TTN | c.47470A>G p.K15824E (on ENST00000591111; = p.K8400E on NM_003319.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | PolyPhen possibly damaging (0.819); catalogued as COSV100598500; called by muse, mutect2, varscan2
- TTN | c.38887A>T p.I12963F (on ENST00000591111; = p.I5539F on NM_003319.4) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | PolyPhen benign (0.143); catalogued as COSV100598502; called by muse, mutect2, varscan2
- UTP14A | c.1979A>T p.K660I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV100928931; called by muse, mutect2, varscan2
- UPF1 | c.415dup p.T139Nfs*64 | Frame Shift Ins (INS) | VAF 43/141 reads (30%) | called by mutect2, pindel, varscan2
- CACNG2 | c.753C>T p.D251= | Silent (SNP) | VAF 12/153 reads (8%) | catalogued as COSV100268606; called by muse, mutect2
- DCUN1D5 | c.372A>G p.K124= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as rs1220445143, COSV99498949; called by muse, mutect2, varscan2
- DDX19A | c.1119G>A p.A373= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs189321243, COSV100156195; called by muse, mutect2, varscan2
- GLUD2 | c.231C>T p.G77= | Silent (SNP) | VAF 53/112 reads (47%) | catalogued as COSV60152327; called by muse, mutect2, varscan2
- IBSP | c.537C>A p.T179= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV99883413; called by muse, mutect2, varscan2
- KCNH1 | c.28C>T p.L10= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV99657720; called by muse, mutect2, varscan2
- KRT19 | c.1008G>A p.A336= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs776581437, COSV99562908; called by muse, mutect2, varscan2
- OPRK1 | c.849C>T p.F283= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs201485656; called by muse, mutect2, varscan2
- PTPRC | c.825A>G p.E275= | Silent (SNP) | VAF 56/156 reads (36%) | catalogued as rs777374286, COSV100722214; called by muse, mutect2, varscan2
- SEC16A | c.69C>T p.S23= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs754365697, COSV99256561; called by muse, mutect2, varscan2
- TMEM143 | c.306G>A p.A102= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs771583460, COSV53155409; called by muse, mutect2, varscan2
- TRIML1 | c.1266C>T p.N422= | Silent (SNP) | VAF 64/128 reads (50%) | catalogued as rs145647080; called by muse, mutect2, varscan2
- UQCC2 | c.351C>A p.P117= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV100951970; called by muse, mutect2, varscan2
- ZNF700 | c.822G>A p.G274= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs1172214606, COSV54312493; called by muse, mutect2, varscan2
- ISCA1P1 | n.157C>T | RNA (SNP) | VAF 32/106 reads (30%) | called by muse, mutect2, varscan2
- RRM2 | n.671G>A | RNA (SNP) | VAF 24/76 reads (32%) | catalogued as rs556910395; called by muse, mutect2, varscan2
